Surgical pathology report (de-identified scan), TCGA case TCGA-HC-A76W, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-HC-A76W-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY:

PROCEDURE DATE:

RECEIVED DATE:

REPORT DATE:

COPY TO: [REDACTED]

CLACK ICD O-3
Adenocarcinoma Acinar
path NOS 8/40/3
Adenocarcinoma NOS 8/40/3
Site Prostate NOS
G61.9
7/28/19/13

Pre-Op Diagnosis

Prostate cancer

Post-Op Diagnosis

Same

Clinical History

Nothing indicated on requisition

Gross Description:

Received in a single container labeled "[REDACTED]" - prostate and left lymph nodes." The specimen was received fresh and intact and then was inked and sectioned for genomic studies. The now fixed prostate gland with attached bilateral seminal vesicles weighs as received 41 grams. Within the specimen container are three tissue cassettes labeled "[REDACTED]". The prostate gland on reconstruction is approximately 5.0 x 4.0 x 4.0 cm with a shaggy outer surface. The urethra appears grossly patent; however, there appears to be compression of the urethra by the lateral lobes.

The cut surface shows multi-nodular rubbery bulging tan gray fibrotic tissue. Noted in the left lateral aspect at a point approximately 0.5 cm from the apical (distal) margin there is a poorly defined approximately 1.0 x 1.0 x 0.7 cm area of tan gray rubbery fibrotic tissue which is poorly defined focally extending to within 0.1 cm of the nearest inked surface. Additionally noted in the left posterior lobe near the vesical (proximal) margin is a second 2.0 x 1.5 x 1.0 cm poorly defined area of similar discoloration which focally extends to within 0.2 cm of the nearest inked surface. This is seen approximately 0.5 cm from the proximal (vesical) margin grossly and grossly appears to extend to the origin of the seminal vesicles. The seminal vesicles together are 4.2 x 1.0 x 1.0 cm with fragmented outer surfaces and multi-cystic tan gray fibrotic cut surfaces. On the left side this gray tan fibrotic tissue extends for a length of 1.2 cm from the origin infiltrating

[page 2 of 3]
into the seminal vesicle. The right seminal vesicle appears to be less involved by this process grossly.

Also received in the same container are 4.0 x 3.2 x 1.0 cm of tan yellow fibroadipose tissue fragments which on palpation and sectioning reveal a few poorly defined indurated tan yellow nodular regions up to 1.1 cm. Representative sections are submitted labeled as follows: A - radial apical (distal) margin, left; B - radial apical (distal) margin, right; C - shave vesical (proximal) margin; D - left lateral lobe distal; E - right lateral lobe distal; F - left posterior lobe distal; G - right posterior lobe distal; H - left lateral lobe mid region; I - right lateral lobe mid region; J - left posterior lobe mid region; K - right posterior lobe mid region; L - left lateral lobe proximal region; M - right lateral lobe proximal region; N - left posterior lobe proximal region; O - right posterior lobe proximal region; P - origin of the seminal vesicles; Q - representative left seminal vesicle; R - representative right seminal vesicle; S and T - apparent nodular areas from separate adipose tissue.

Microscopic Description:

The slides labeled [REDACTED] are examined. See diagnosis.

Final Diagnosis

Prostate (radical prostatectomy):

Prostate size:

Weight: 41 grams.

Size: 5.0 x 4.0 x 4.0 cm.

Histologic type: Adenocarcinoma.

Histologic grade (Gleason pattern):

Primary pattern: Grade 3

Secondary pattern: Grade 4

Tertiary pattern: Grade 5

Total Gleason score: 3+4 + 7

Tumor quantification: Tumor size of dominant nodule: 2.0 cm.

Extraprostatic extension: Present, focally (see comment).

Seminal vesicle invasion: Present, both right and left seminal vesicle involved.

Margin status:

Tumor extends to cauterized margin along the left posterior lobe proximal region consistent with transection.

Bladder neck: No carcinoma identified.

Apical inferior margin: Carcinoma extends to within 1 mm of the inked margin.

Treatment effect: Not identified (correlate clinically).

Lymphovascular space invasion: No unequivocal lymphovascular space invasion identified. PAS 9

Lymph nodes, left pelvic lymph nodes, regional resection:

Reactive sinus histiocytosis and fatty infiltration, no metastatic carcinoma identified within four lymph nodes (0/4) PAS 4

CPT: 88309, 88307

Stage: pT3bN0 (see comment)

Comments

[page 3 of 3]
This is staged as a pT3b lesion based on involvement of the seminal vesicle bilaterally. Please note it is staged as a pN0 lesion as there are no regional lymph node metastases, however, only one side of the pelvic nodes (left) were resected. Clinical correlation and follow up is recommended.

At the left posterior proximal region, carcinoma extends up to the cauterized margin consistent with transection. In addition, carcinoma extends into the fibroadipose tissue in this region consistent with extraprostatic extension. Clinical correlation and follow up is recommended.

At the request of the undersigned pathologist, these slides have been additionally reviewed by Dr. [REDACTED], who concurs with the diagnosis.

This report has been finalized at the [REDACTED]

<Sign Out Dr. Signature>

hw 8/2/13
Kmt
Carcinoma Melanoma - pT3b

Source: NCI Genomic Data Commons file 7617cedc-ab27-4411-88d2-7654d3aa2a78 (TCGA-HC-A76W.C59C0C25-B1FC-45C5-AD7E-0FBA9574656C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).